CCDI case PBBPKI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/79867412-e6ab-481f-8dd3-8be8b4911e07

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 2.5 years (899 days).

Biospecimens (3 samples)
- Sample 0DEA0L: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DEA0P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DEA0V: Tissue type: Tumor; Specimen type: Solid Tissue.
